Somatic mutation profile of tumor specimen ALCH-B357-TTP1-A (aliquot ALCH-B357-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B357, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 79.5 years (29,039 days).
Specimen ALCH-B357-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf4bbc59-4c37-4ce4-8af7-65abaa59c22d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B357-NB1-A (Blood Derived Normal), aliquot ALCH-B357-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9f608c3-a504-4881-9cd6-e74dd4ac5276

The open-access MAF lists 989 somatic variants for this specimen: 665 protein-altering or splice-affecting, 198 silent, 126 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 558, Silent 198, Intron 56, Frame Shift Del 33, Nonsense Mutation 28, Splice Site 25, RNA 20, 3'UTR 14, 5'Flank 14, 5'UTR 12, 3'Flank 10, Frame Shift Ins 9.

Variants (750 of 989; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.126T>G p.N42K | Missense Mutation (SNP) | VAF 19/155 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXG1 | c.1439A>G p.Q480R | Missense Mutation (SNP) | VAF 117/640 reads (18%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.932); catalogued as rs148410675; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- STK11 | c.751G>T p.G251C | Missense Mutation (SNP) | VAF 15/93 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM981868, COSV58822591, COSV58830751; called by muse, mutect2, varscan2
- ABCG2 | c.1737G>T p.T579= | Splice Region (SNP) | VAF 38/280 reads (14%) | catalogued as COSV52942823; called by muse, mutect2, varscan2
- ACSM2B | c.1647C>A p.N549K | Missense Mutation (SNP) | VAF 57/347 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs1191942535; called by muse, mutect2, varscan2
- ADAM29 | c.2028C>A p.F676L | Missense Mutation (SNP) | VAF 55/305 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.017); catalogued as rs760647414; called by muse, mutect2, varscan2
- ADCY10 | c.2026G>T p.V676F | Missense Mutation (SNP) | VAF 44/560 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV63241547; called by muse, mutect2
- ADGRL3 | c.2540C>A p.S847Y (on ENST00000506720 / NM_001322402.2; = p.S779Y on NM_015236.6) | Missense Mutation (SNP) | VAF 44/337 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72230143; called by muse, mutect2, varscan2
- AGO1 | c.1074G>T p.Q358H | Missense Mutation (SNP) | VAF 40/552 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100940923; called by muse, mutect2
- AHNAK | c.3697G>A p.G1233R | Missense Mutation (SNP) | VAF 166/921 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV57204358; called by muse, mutect2, varscan2
- ALDH9A1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 28/300 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as rs1185553838; called by muse, mutect2
- AMER1 | c.1087G>C p.V363L | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100365058; called by muse, mutect2, varscan2
- AMOTL1 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 127/592 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54418253; called by muse, mutect2, varscan2
- AMTN | c.386A>G p.H129R | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.173); catalogued as rs780237962; called by muse, mutect2, varscan2
- ANGPT1 | c.476T>A p.L159H | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52433601; called by muse, mutect2
- ANK1 | c.1717del p.L573Cfs*64 | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | catalogued as CD014448; called by mutect2, pindel, varscan2
- ANKRD17 | c.4910A>G p.N1637S | Missense Mutation (SNP) | VAF 68/364 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs763017450, COSV58225379; called by muse, mutect2, varscan2
- APCDD1L | c.403G>A p.V135I | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.749); catalogued as rs1488179315; called by muse, mutect2
- ARFGEF3 | c.5503G>T p.E1835* | Nonsense Mutation (SNP) | VAF 128/325 reads (39%) | catalogued as COSV52454824; called by muse, mutect2, varscan2
- ASIC2 | c.987G>T p.G329= | Splice Region (SNP) | VAF 28/305 reads (9%) | catalogued as COSV99861380; called by muse, mutect2
- ASTN1 | c.2869G>T p.E957* | Nonsense Mutation (SNP) | VAF 33/241 reads (14%) | catalogued as COSV62490027, COSV62491543; called by muse, mutect2, varscan2
- ATM | c.8762C>A p.T2921K | Missense Mutation (SNP) | VAF 68/459 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs730881329, COSV53726751; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AXIN1 | c.2187-1G>T p.X729_splice | Splice Site (SNP) | VAF 20/234 reads (9%) | catalogued as rs1461736230; called by muse, mutect2
- BAHD1 | c.1886G>T p.R629L | Missense Mutation (SNP) | VAF 58/379 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV69084137; called by muse, mutect2, varscan2
- BANK1 | c.203G>T p.R68L | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.145); catalogued as rs369642143; called by muse, mutect2, varscan2
- BMP2 | c.93G>T p.R31S | Missense Mutation (SNP) | VAF 56/307 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.112); catalogued as COSV66577964; called by muse, mutect2, varscan2
- BOC | c.1223C>A p.T408N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as rs1404105295, COSV99849338; called by muse, mutect2, varscan2
- BRD9 | c.1732G>T p.V578F | Missense Mutation (SNP) | VAF 95/319 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.258); catalogued as rs374226502; called by muse, mutect2, varscan2
- BRDT | c.2113C>A p.Q705K | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs1042624934; called by muse, mutect2, varscan2
- BTBD16 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99584450; called by muse, mutect2
- C17orf99 | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 73/571 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as rs1040552586; called by muse, varscan2
- C1QC | c.587C>A p.T196K | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.045); catalogued as COSV65890095; called by muse, mutect2, varscan2
- C1QTNF2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs756501356; called by muse, mutect2, varscan2
- CARMIL2 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.706); catalogued as rs948490082, COSV58024112; called by muse, mutect2, varscan2
- CCDC102B | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as rs199750681; called by muse, mutect2, varscan2
- CDH18 | c.1996G>T p.E666* | Nonsense Mutation (SNP) | VAF 34/588 reads (6%) | catalogued as COSV56923749; called by muse, mutect2
- CDH2 | c.2165C>T p.T722I | Missense Mutation (SNP) | VAF 105/398 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.864); catalogued as rs781525713; called by muse, mutect2, varscan2
- CDK13 | c.4157A>T p.H1386L | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.535); catalogued as rs1050882710, COSV99476272; called by muse, mutect2, varscan2
- CELSR1 | c.4283G>T p.C1428F | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53091033; called by muse, mutect2, varscan2
- CELSR1 | c.814A>G p.T272A | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs1272716730; called by muse, mutect2, varscan2
- CENPB | c.227A>G p.K76R | Missense Mutation (SNP) | VAF 39/279 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.144); catalogued as rs1169850506; called by muse, mutect2, varscan2
- CENPV | c.652G>T p.V218F | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV55333443; called by muse, mutect2, varscan2
- CFAP61 | c.2408C>G p.T803R | Missense Mutation (SNP) | VAF 62/523 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.875); catalogued as COSV55619741, COSV55624296; called by muse, mutect2, varscan2
- CHD2 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 26/406 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.091); catalogued as rs1555438837; ClinVar: uncertain significance; called by muse, mutect2
- CLEC11A | c.630C>A p.S210R | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs764470824; called by muse, mutect2, varscan2
- CNBD1 | c.1276G>T p.A426S | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV73074811; called by muse, mutect2, varscan2
- CNTNAP3 | c.2174G>T p.G725V | Missense Mutation (SNP) | VAF 22/507 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs1319691507; called by muse, mutect2
- CNTROB | c.870G>T p.E290D | Missense Mutation (SNP) | VAF 135/610 reads (22%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.457); catalogued as COSV66607437; called by muse, mutect2, varscan2
- COL11A1 | c.3725C>G p.P1242R | Missense Mutation (SNP) | VAF 123/623 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.109); catalogued as rs1178882531, COSV62172715; called by muse, mutect2, varscan2
- COL4A1 | c.3048G>T p.M1016I | Missense Mutation (SNP) | VAF 227/985 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.899); catalogued as COSV65433810; called by muse, mutect2, varscan2
- COPA | c.2675T>A p.L892Q | Missense Mutation (SNP) | VAF 59/443 reads (13%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.691); catalogued as rs750834336; called by muse, mutect2, varscan2
- CRAT | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs751822013, COSV58875880; called by muse, mutect2, varscan2
- CSMD3 | c.10781G>A p.G3594E (on ENST00000297405 / NM_001363185.1; = p.G3425E on NM_052900.3) | Missense Mutation (SNP) | VAF 43/350 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV52173581; called by muse, mutect2, varscan2
- CSMD3 | c.10667T>C p.I3556T (on ENST00000297405 / NM_001363185.1; = p.I3387T on NM_052900.3) | Missense Mutation (SNP) | VAF 54/301 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV52253818; called by muse, mutect2, varscan2
- CWH43 | c.1909G>C p.E637Q | Missense Mutation (SNP) | VAF 21/228 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104389487; called by muse, mutect2
- CYP11B2 | c.208C>A p.Q70K | Missense Mutation (SNP) | VAF 104/555 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.05); catalogued as COSV59996000; called by muse, mutect2, varscan2
- DBX2 | c.434C>A p.P145Q | Missense Mutation (SNP) | VAF 49/385 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as rs1051730537, COSV60339007; called by muse, mutect2, varscan2
- DCDC1 | c.4271G>T p.R1424L (on ENST00000597505 / NM_001367979.1; = p.R531L on NM_020869.3) | Missense Mutation (SNP) | VAF 58/415 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.133); catalogued as rs754104310, COSV58004437; called by muse, mutect2, varscan2
- DCHS1 | c.8696G>A p.R2899K | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1350107881; called by muse, mutect2, varscan2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 14/118 reads (12%) | catalogued as rs754135731; called by mutect2, varscan2*
- DEDD2 | c.649G>T p.V217L | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV60143099; called by muse, mutect2, varscan2
- DGKI | c.2262G>T p.W754C | Missense Mutation (SNP) | VAF 37/293 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.04); catalogued as rs1267393854; called by muse, mutect2, varscan2
- DLG1 | c.218C>G p.S73C | Missense Mutation (SNP) | VAF 54/380 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs749018763; called by muse, mutect2, varscan2
- DLGAP3 | c.1238C>A p.P413H | Missense Mutation (SNP) | VAF 76/538 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV52395827; called by muse, mutect2, varscan2
- DNAH3 | c.7709G>T p.G2570V | Missense Mutation (SNP) | VAF 19/265 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54519026; called by muse, mutect2
- DNAH5 | c.541C>T p.H181Y | Missense Mutation (SNP) | VAF 427/1067 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV54242393; called by muse, mutect2, varscan2
- DPYD | c.1706G>T p.G569V | Missense Mutation (SNP) | VAF 90/447 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV64616174; called by muse, mutect2, varscan2
- DSP | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 212/657 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs368193211, CM1413441; called by muse, mutect2, varscan2
- DYTN | c.1663T>A p.Y555N | Missense Mutation (SNP) | VAF 85/489 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1382947640; called by muse, mutect2, varscan2
- EFEMP1 | c.131-1G>C p.X44_splice | Splice Site (SNP) | VAF 52/402 reads (13%) | catalogued as COSV62617237; called by muse, mutect2, varscan2
- ERP27 | c.254T>C p.V85A | Missense Mutation (SNP) | VAF 114/674 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as rs1565454382; called by muse, mutect2, varscan2
- ETAA1 | c.2741G>A p.R914Q | Missense Mutation (SNP) | VAF 62/507 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1402635743; called by muse, mutect2, varscan2
- EYA1 | c.1423A>G p.T475A | Missense Mutation (SNP) | VAF 109/860 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58157814; called by muse, mutect2, varscan2
- FAM120A | c.2516G>T p.R839L | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52903994; called by muse, mutect2, varscan2
- FAM181A | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV50887889; called by muse, mutect2, varscan2
- FBXO40 | c.568G>T p.G190W | Missense Mutation (SNP) | VAF 57/238 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV57522300; called by muse, mutect2, varscan2
- FCRL3 | c.1113G>A p.W371* | Nonsense Mutation (SNP) | VAF 31/146 reads (21%) | catalogued as rs1443534307; called by muse, mutect2, varscan2
- FLG | c.4294G>A p.G1432R | Missense Mutation (SNP) | VAF 49/612 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs145478188, COSV64235797; called by muse, mutect2
- FLG | c.345G>C p.Q115H | Missense Mutation (SNP) | VAF 131/761 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs754930940; called by muse, mutect2, varscan2
- FRYL | c.8422G>A p.G2808S | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.313); catalogued as rs747549744; called by muse, mutect2
- FSHR | c.138G>T p.R46S | Missense Mutation (SNP) | VAF 154/1016 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as COSV100436532; called by muse, mutect2, varscan2
- GABRA4 | c.421G>T p.V141F | Missense Mutation (SNP) | VAF 29/281 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV51935918; called by muse, mutect2, varscan2
- GC | c.1029G>T p.M343I | Missense Mutation (SNP) | VAF 68/342 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99910144; called by muse, mutect2, varscan2
- GIMAP1 | c.228C>A p.C76* | Nonsense Mutation (SNP) | VAF 26/259 reads (10%) | catalogued as COSV100212005; called by muse, mutect2, varscan2
- GPR149 | c.725dup p.P243Sfs*44 | Frame Shift Ins (INS) | VAF 33/181 reads (18%) | catalogued as rs1559993608; called by mutect2, pindel, varscan2
- GREB1L | c.2168G>A p.R723Q | Missense Mutation (SNP) | VAF 133/815 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs754346764; called by muse, mutect2, varscan2
- GTF2E1 | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375390678; called by muse, mutect2
- HAND2 | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 71/302 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV64017586; called by muse, mutect2, varscan2
- HERC2 | c.9161C>T p.S3054L | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267604146; called by muse, mutect2, varscan2
- HIF3A | c.737G>T p.S246I (on ENST00000377670 / NM_152795.4; = p.S177I on NM_022462.4) | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV52206013; called by muse, mutect2, varscan2
- IFNA4 | c.205C>A p.H69N | Missense Mutation (SNP) | VAF 43/324 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs16938293; called by muse, mutect2, varscan2
- IHH | c.200A>G p.Y67C | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.912); catalogued as rs768675737; called by muse, mutect2, varscan2
- IL16 | c.484A>T p.T162S | Missense Mutation (SNP) | VAF 54/630 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.079); catalogued as rs751791636; called by muse, mutect2
- IMPG2 | c.3214G>T p.G1072W | Missense Mutation (SNP) | VAF 103/618 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99515755; called by muse, mutect2, varscan2
- INSR | c.411G>T p.M137I | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as COSV57157479; called by muse, mutect2, varscan2
- INSRR | c.2740G>A p.E914K | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.527); catalogued as rs1160318683; called by muse, mutect2
- IRX1 | c.429G>C p.K143N | Missense Mutation (SNP) | VAF 53/439 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100116422; called by muse, mutect2, varscan2
- JAG2 | c.611G>A p.S204N | Missense Mutation (SNP) | VAF 50/537 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.801); catalogued as COSV59313101; called by muse, mutect2
- KCNH6 | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144043788; called by muse, mutect2, varscan2
- KIAA2026 | c.1294G>T p.G432C | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1163498749; called by muse, mutect2
- KIF26A | c.5614G>A p.A1872T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs769160513; called by muse, mutect2, varscan2
- KIF2B | c.625C>A p.P209T | Missense Mutation (SNP) | VAF 31/310 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99276469; called by muse, mutect2, varscan2
- KIF2B | c.1047C>A p.D349E | Missense Mutation (SNP) | VAF 59/273 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs1282766997; called by muse, mutect2, varscan2
- KIF5C | c.2623C>A p.R875S | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1310431752, COSV101276225; called by muse, mutect2, varscan2
- KMT2B | c.2508C>G p.I836M | Missense Mutation (SNP) | VAF 21/259 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1265433345; called by muse, mutect2
- KPRP | c.1330C>A p.P444T | Missense Mutation (SNP) | VAF 62/361 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1489637283; called by muse, mutect2, varscan2
- KRTAP10-12 | c.18C>A p.S6R | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs191466912, COSV59983201; called by muse, mutect2
- LAMA5 | c.3713A>T p.Q1238L | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1266062311; called by muse, mutect2, varscan2
- LAMA5 | c.3031G>T p.V1011F | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1210928835; called by muse, mutect2, varscan2
- LHFPL5 | c.46A>T p.T16S | Missense Mutation (SNP) | VAF 58/292 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as COSV100798954; called by muse, mutect2, varscan2
- LILRA6 | c.1276A>T p.S426C | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs1330814997; called by muse, mutect2
- LILRB5 | c.1687C>T p.L563F (on ENST00000449561 / NM_001081442.3; = p.L562F on NM_006840.5) | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.164); catalogued as COSV100300552; called by muse, mutect2, varscan2
- LRP1B | c.11876C>A p.A3959E | Missense Mutation (SNP) | VAF 38/223 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs781576057, COSV101259043; called by muse, mutect2, varscan2
- LRRC7 | c.605G>T p.R202L (on ENST00000651989 / NM_001370785.2; = p.R169L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as COSV50570422; called by muse, varscan2
- LY9 | c.214G>C p.D72H | Missense Mutation (SNP) | VAF 47/584 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV54435922; called by muse, mutect2
- MAGEC2 | c.246C>A p.S82R | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.928); catalogued as COSV55998018, COSV56000658; called by muse, mutect2, varscan2
- MAGIX | c.448C>G p.P150A | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV66256721; called by muse, mutect2, varscan2
- MAP3K10 | c.1558C>G p.P520A | Missense Mutation (SNP) | VAF 121/422 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV53425796; called by muse, mutect2, varscan2
- MB21D2 | c.682A>G p.S228G | Missense Mutation (SNP) | VAF 66/449 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs1175854848; called by muse, mutect2, varscan2
- MGAM | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 34/387 reads (9%) | catalogued as COSV71884944; called by muse, mutect2
- MKRN3 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as rs772698198, COSV58809061; called by muse, mutect2, varscan2
- MMEL1 | c.2001+1G>A p.X667_splice | Splice Site (SNP) | VAF 17/133 reads (13%) | catalogued as rs772972972; called by muse, mutect2, varscan2
- MOCOS | c.1219G>T p.V407L | Missense Mutation (SNP) | VAF 83/378 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV54346211; called by muse, mutect2, varscan2
- MRPL50 | c.25A>G p.I9V | Missense Mutation (SNP) | VAF 63/369 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1337880904; called by muse, mutect2, varscan2
- MTHFD1 | c.1097G>T p.R366L | Missense Mutation (SNP) | VAF 61/589 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs540581926, COSV53702265; called by muse, mutect2, varscan2
- MTUS2 | c.2573C>G p.S858C | Missense Mutation (SNP) | VAF 79/416 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1255954590, COSV99079521; called by muse, mutect2, varscan2
- MTX3 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 17/121 reads (14%) | catalogued as COSV101560471; called by muse, mutect2, varscan2
- MUC16 | c.26534C>G p.P8845R | Missense Mutation (SNP) | VAF 81/411 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV67479610; called by muse, mutect2, varscan2
- MUC16 | c.14828C>T p.P4943L | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.083); catalogued as COSV67456064; called by muse, mutect2, varscan2
- MUC17 | c.6299G>T p.G2100V | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.429); catalogued as COSV100072354; called by muse, mutect2, varscan2
- NAV3 | c.4082C>T p.P1361L | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs751841384, COSV57116183; called by muse, mutect2
- NBPF6 | c.220del p.D74Mfs*33 | Frame Shift Del (DEL) | VAF 34/348 reads (10%) | catalogued as COSV99640698; called by mutect2, varscan2
- NLRP3 | c.2812G>T p.D938Y | Missense Mutation (SNP) | VAF 100/575 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV100275167; called by muse, mutect2, varscan2
- NPAP1 | c.965G>T p.R322L | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.167); catalogued as COSV100274668, COSV100276294; called by muse, mutect2, varscan2
- NUP155 | c.3181G>T p.E1061* (on ENST00000231498 / NM_153485.3; = p.E1002* on NM_004298.4) | Nonsense Mutation (SNP) | VAF 30/576 reads (5%) | catalogued as COSV99193921; called by muse, mutect2
- NYNRIN | c.1607G>C p.G536A | Missense Mutation (SNP) | VAF 45/321 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs750261872; called by muse, mutect2, varscan2
- OPA1 | c.740G>T p.R247L (on ENST00000361510 / NM_130837.3; = p.R211L on NM_130832.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/387 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as rs138350727, CM081724; called by muse, mutect2, varscan2
- OR10K1 | c.685C>A p.P229T | Missense Mutation (SNP) | VAF 90/676 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.542); catalogued as COSV56870588; called by muse, varscan2
- OR1K1 | c.305T>A p.M102K | Missense Mutation (SNP) | VAF 62/319 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV52956514; called by muse, mutect2, varscan2
- OR52D1 | c.819del p.K274Sfs*35 | Frame Shift Del (DEL) | VAF 47/488 reads (10%) | catalogued as COSV59487045; called by mutect2, pindel, varscan2
- OR5F1 | c.694del p.E232Rfs*14 | Frame Shift Del (DEL) | VAF 35/210 reads (17%) | catalogued as COSV99558770; called by mutect2, pindel, varscan2
- P3H3 | c.1507C>G p.P503A | Missense Mutation (SNP) | VAF 45/302 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99300871; called by muse, mutect2, varscan2
- PAGE1 | c.167-1G>T p.X56_splice | Splice Site (SNP) | VAF 21/101 reads (21%) | catalogued as COSV101093987; called by muse, mutect2, varscan2
- PAPPA2 | c.3914G>A p.R1305H | Missense Mutation (SNP) | VAF 83/476 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs771937888, COSV62796581; called by muse, mutect2, varscan2
- PARD3B | c.3587G>T p.R1196L (on ENST00000406610 / NM_001302769.2; = p.R1127L on NM_057177.7) | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62513903; called by muse, mutect2, varscan2
- PARP3 | c.1165G>T p.A389S | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs373811748; called by muse, mutect2, varscan2
- PAX3 | c.1090T>A p.S364T | Missense Mutation (SNP) | VAF 119/700 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.536); catalogued as COSV60590218; called by muse, mutect2, varscan2
- PCDH8 | c.1864G>T p.A622S | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0.038); catalogued as rs1234537063; called by muse, mutect2, varscan2
- PCDHB11 | c.2221G>A p.G741S | Missense Mutation (SNP) | VAF 58/506 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.185); catalogued as rs1554285778; called by muse, mutect2, varscan2
- PCDHB14 | c.184C>A p.R62S | Missense Mutation (SNP) | VAF 40/349 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs781907552; called by muse, mutect2, varscan2
- PCDHB2 | c.1961G>C p.R654P | Missense Mutation (SNP) | VAF 74/402 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.88); catalogued as rs1554271620, COSV50635923; called by muse, mutect2, varscan2
- PGR | c.1954G>A p.D652N | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.889); catalogued as COSV99679121; called by muse, mutect2, varscan2
- PIK3CG | c.180C>A p.H60Q | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV63251677; called by muse, mutect2, varscan2
- PKD2 | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 123/806 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs1208947229, COSV52937665; called by muse, mutect2, varscan2
- PKHD1L1 | c.7527C>G p.H2509Q | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV101006814; called by muse, mutect2, varscan2
- PLD2 | c.208G>T p.V70L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.82); PolyPhen benign (0.011); catalogued as rs112526737; called by muse, mutect2, varscan2
- PLEKHG2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs770436349; called by muse, mutect2, varscan2
- PLXND1 | c.2216G>A p.R739Q | Missense Mutation (SNP) | VAF 60/281 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs138740853; called by muse, mutect2, varscan2
- PPP2R5D | c.1482-3C>T | Splice Region (SNP) | VAF 38/531 reads (7%) | catalogued as COSV99775630; called by muse, mutect2
- PRDM14 | c.1058G>A p.C353Y | Missense Mutation (SNP) | VAF 67/589 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.277); catalogued as rs750600524, COSV52571688; called by muse, mutect2, varscan2
- PREX2 | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 81/543 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1372641862; called by muse, mutect2, varscan2
- PRKD1 | c.2467A>T p.K823* | Nonsense Mutation (SNP) | VAF 22/299 reads (7%) | catalogued as rs889475068, COSV59585153; called by muse, mutect2
- PRKDC | c.2430G>T p.K810N | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.142); catalogued as COSV100041080; called by muse, mutect2, varscan2
- PRKX | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV53327819; called by muse, mutect2, varscan2
- PRR23B | c.341C>A p.A114E | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as COSV61494310; called by muse, mutect2, varscan2
- PTPRD | c.4910C>A p.T1637K | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs41281783, COSV61953635; called by muse, mutect2
- PTPRT | c.1513C>A p.Q505K | Missense Mutation (SNP) | VAF 82/600 reads (14%) | SIFT tolerated (0.95); PolyPhen benign (0.014); catalogued as COSV62002441; called by muse, mutect2, varscan2
- RAB19 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 52/536 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs576701732, COSV99325114; called by muse, mutect2
- RGPD3 | c.4200C>A p.D1400E | Missense Mutation (SNP) | VAF 82/510 reads (16%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.994); catalogued as rs1330766308, COSV58744657; called by mutect2, varscan2
- RGS7 | c.782A>G p.Q261R | Missense Mutation (SNP) | VAF 44/279 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.392); catalogued as COSV100467715, COSV100470519; called by muse, mutect2, varscan2
- RYR2 | c.2440C>G p.L814V | Missense Mutation (SNP) | VAF 66/415 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.656); catalogued as COSV63663894; called by muse, mutect2, varscan2
- RYR2 | c.12477G>T p.Q4159H | Missense Mutation (SNP) | VAF 39/202 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1558405653; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- S100A8 | c.260A>G p.H87R | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs529746869, COSV64197981; called by muse, mutect2, varscan2
- SCN3B | c.220-1G>T p.X74_splice | Splice Site (SNP) | VAF 104/472 reads (22%) | catalogued as rs1416986779, COSV54798711; called by muse, mutect2, varscan2
- SEC16B | c.2069G>T p.R690L | Missense Mutation (SNP) | VAF 33/315 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.29); catalogued as COSV57624369; called by muse, mutect2, varscan2
- SEMA5A | c.2047G>T p.G683W | Missense Mutation (SNP) | VAF 32/357 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101228645; called by muse, mutect2
- SHROOM4 | c.2120C>A p.P707Q | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV56786903; called by muse, mutect2, varscan2
- SLC16A9 | c.435A>T p.T145= | Splice Region (SNP) | VAF 62/336 reads (18%) | catalogued as rs759835645; called by muse, mutect2, varscan2
- SLC25A12 | c.165G>T p.K55N | Missense Mutation (SNP) | VAF 191/796 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV55537991; called by muse, mutect2, varscan2
- SLC35G6 | c.333C>A p.N111K | Missense Mutation (SNP) | VAF 92/434 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); catalogued as COSV59494082; called by muse, varscan2
- SLC4A2 | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100055472, COSV59655765; called by muse, mutect2, varscan2
- SLIT3 | c.488A>T p.Q163L | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as rs374568304; called by muse, mutect2
- SPOP | c.581G>A p.W194* | Nonsense Mutation (SNP) | VAF 99/509 reads (19%) | catalogued as COSV61654057; called by muse, mutect2, varscan2
- SPPL2C | c.170C>A p.P57Q | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV100234078; called by muse, mutect2, varscan2
- SPTBN4 | c.4835G>T p.R1612L | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.757); catalogued as rs1323947242; called by muse, mutect2, varscan2
- SRRM4 | c.1378T>A p.Y460N | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV57424642; called by muse, mutect2, varscan2
- ST3GAL6 | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 30/544 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs1559741277; called by muse, mutect2
- STXBP1 | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 76/682 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.386); catalogued as rs751437146; called by muse, mutect2, varscan2
- SULF2 | c.1666G>T p.A556S | Missense Mutation (SNP) | VAF 87/452 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.023); catalogued as COSV63417386; called by muse, mutect2, varscan2
- SUN1 | c.802G>A p.G268R (on ENST00000405266 / NM_001367651.1; = p.G231R on NM_001130965.3 and 17 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 136/514 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.08); catalogued as rs753073325; called by muse, mutect2, varscan2
- SV2C | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV59217261; called by muse, mutect2
- SYNE2 | c.16408G>T p.G5470C | Missense Mutation (SNP) | VAF 42/233 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as COSV59971960; called by muse, mutect2, varscan2
- TBX3 | c.1169G>T p.C390F (on ENST00000257566 / NM_016569.4; = p.C370F on NM_005996.4) | Missense Mutation (SNP) | VAF 26/371 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.203); catalogued as COSV57473069; called by muse, mutect2
- TENM1 | c.3665C>T p.S1222L | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs747368597, COSV64424199; called by muse, mutect2, varscan2
- TIGD1 | c.1640C>T p.P547L | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374434407; called by muse, mutect2
- TMEM61 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 48/231 reads (21%) | catalogued as COSV99054975; called by muse, mutect2, varscan2
- TNFRSF13B | c.787A>G p.T263A | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768133177; called by muse, mutect2, varscan2
- TRIM48 | c.483G>C p.Q161H | Missense Mutation (SNP) | VAF 78/587 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs778818376; called by muse, mutect2, varscan2
- TRIM51GP | c.956C>A p.P319H | Missense Mutation (SNP) | VAF 64/381 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs986619530; called by muse, mutect2, varscan2
- TRIM58 | c.813G>C p.M271I | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV63569755; called by muse, mutect2, varscan2
- TRPV4 | c.812G>T p.R271L | Missense Mutation (SNP) | VAF 70/313 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.326); catalogued as CM118758; called by muse, mutect2, varscan2
- TTBK1 | c.1316del p.P439Qfs*16 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | catalogued as COSV104389590; called by mutect2, pindel, varscan2
- TTC37 | c.2011+1G>T p.X671_splice | Splice Site (SNP) | VAF 25/193 reads (13%) | catalogued as COSV62456803; called by muse, mutect2, varscan2
- TTLL8 | c.2158G>T p.D720Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs1369303281; called by muse, mutect2, varscan2
- TTN | c.3362C>T p.P1121L (on ENST00000591111; = p.P1075L on NM_003319.4) | Missense Mutation (SNP) | VAF 94/710 reads (13%) | PolyPhen probably damaging (0.934); catalogued as rs1481460838, COSV59989643; called by muse, mutect2, varscan2
- TULP1 | c.1246C>A p.R416S | Missense Mutation (SNP) | VAF 42/522 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as CM149203, COSV57692082; called by muse, mutect2
- UBE3D | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 41/269 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV52757759; called by muse, mutect2, varscan2
- UNC45A | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs537021201; called by muse, mutect2, varscan2
- USH2A | c.2365G>C p.V789L | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0.031); catalogued as COSV56356025; called by muse, mutect2, varscan2
- VEGFC | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 16/281 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.685); catalogued as rs201028890, COSV54608824; called by muse, mutect2
- VEGFC | c.806del p.G269Efs*42 | Frame Shift Del (DEL) | VAF 21/124 reads (17%) | catalogued as COSV54595515; called by mutect2, pindel, varscan2
- YLPM1 | c.1210G>T p.G404* | Nonsense Mutation (SNP) | VAF 67/419 reads (16%) | catalogued as COSV53124209; called by muse, mutect2, varscan2
- ZBTB46 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs751567417, COSV55509907; called by muse, mutect2, varscan2
- ZHX2 | c.831G>T p.M277I | Missense Mutation (SNP) | VAF 84/513 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV58716014; called by muse, mutect2, varscan2
- ZNF438 | c.946G>A p.G316S | Missense Mutation (SNP) | VAF 79/379 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV99045403; called by muse, mutect2, varscan2
- ZNF519 | c.1169A>G p.Y390C | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as rs770288525; called by muse, mutect2, varscan2
- ZNF549 | c.314C>A p.S105Y (on ENST00000376233 / NM_001199295.2; = p.S92Y on NM_153263.2) | Missense Mutation (SNP) | VAF 24/459 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV53725751; called by muse, mutect2
- ZNF596 | c.227G>C p.R76T | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs985068189, COSV57655134; called by muse, mutect2, varscan2
- ZNF804B | c.476T>A p.V159E | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.261); catalogued as rs888184927; called by muse, mutect2, varscan2
- ZSCAN1 | c.658C>A p.L220I | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1399001562, COSV56603728; called by muse, mutect2, varscan2
- ABCB5 | c.804-2_804-1del p.X268_splice | Splice Site (DEL) | VAF 15/116 reads (13%) | called by mutect2, pindel, varscan2
- ABCB9 | c.2203G>T p.A735S (on ENST00000280560 / NM_019625.4; = p.A692S on NM_019624.3) | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ABCC8 | c.887G>T p.G296V | Missense Mutation (SNP) | VAF 38/231 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ABHD10 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 54/279 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACAD11 | c.1993T>C p.Y665H | Missense Mutation (SNP) | VAF 49/258 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.01); called by muse, mutect2
- ACSL3 | c.300G>C p.K100N | Missense Mutation (SNP) | VAF 25/234 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ACTA1 | c.334del p.L112Sfs*10 | Frame Shift Del (DEL) | VAF 66/465 reads (14%) | called by mutect2, pindel, varscan2
- ADAD2 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 21/115 reads (18%) | SIFT tolerated, low confidence (0.85); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- ADAM22 | c.2524A>T p.N842Y | Missense Mutation (SNP) | VAF 36/255 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- ADAM23 | c.1831T>C p.C611R | Missense Mutation (SNP) | VAF 97/601 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS19 | c.1196G>T p.G399V | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ADAMTS2 | c.1141C>A p.P381T | Missense Mutation (SNP) | VAF 28/368 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS4 | c.403G>T p.D135Y | Missense Mutation (SNP) | VAF 65/390 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ADCYAP1R1 | c.341T>A p.V114E | Missense Mutation (SNP) | VAF 157/631 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- ADGRL3 | c.480T>A p.N160K (on ENST00000506720 / NM_001322402.2; = p.N92K on NM_015236.6) | Missense Mutation (SNP) | VAF 83/468 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- AKAP7 | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 21/98 reads (21%) | called by muse, mutect2, varscan2
- ALOX15 | c.1607G>T p.C536F | Missense Mutation (SNP) | VAF 70/313 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ANGPTL1 | c.1232T>C p.M411T | Missense Mutation (SNP) | VAF 56/265 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKRD30B | c.1427T>A p.M476K | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.261); called by muse, varscan2
- ANKRD33B | c.1069C>G p.Q357E | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD34A | c.530G>C p.S177T | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANTXR2 | c.208dup p.A70Gfs*8 | Frame Shift Ins (INS) | VAF 78/525 reads (15%) | called by mutect2, pindel, varscan2
- ANXA7 | c.55-2A>T p.X19_splice | Splice Site (SNP) | VAF 13/121 reads (11%) | called by muse, mutect2, varscan2
- AP2S1 | c.227A>G p.N76S | Missense Mutation (SNP) | VAF 121/390 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- AQP11 | c.255C>G p.F85L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ARHGAP4 | c.576G>T p.E192D | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- ARHGEF33 | c.2060G>A p.S687N | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ARL14EPL | c.111del p.Q38Sfs*2 | Frame Shift Del (DEL) | VAF 45/241 reads (19%) | called by mutect2, pindel, varscan2
- ARPP21 | c.1745T>A p.L582H | Missense Mutation (SNP) | VAF 129/572 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- ARPP21 | c.1943C>A p.T648N | Missense Mutation (SNP) | VAF 86/428 reads (20%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARSI | c.1569G>T p.W523C | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARX | c.1568C>A p.A523E | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- ASMT | c.163del p.A55Pfs*16 | Frame Shift Del (DEL) | VAF 53/345 reads (15%) | called by mutect2, pindel, varscan2
- ATE1 | c.234-2A>T p.X78_splice | Splice Site (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- ATN1 | c.2221G>T p.V741L | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ATRN | c.3040G>A p.G1014R | Missense Mutation (SNP) | VAF 93/663 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BAHCC1 | c.4705G>C p.A1569P | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- BAHCC1 | c.7288G>T p.G2430C | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- BCL2L13 | c.94C>G p.Q32E | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- BEST3 | c.61C>A p.L21I | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BHLHE41 | c.198G>T p.Q66H | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BICRA | c.-5-2A>G | Splice Site (SNP) | VAF 75/239 reads (31%) | called by muse, mutect2, varscan2
- BMP7 | c.958G>C p.E320Q | Missense Mutation (SNP) | VAF 58/418 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- BPI | c.998T>A p.L333Q (on ENST00000262865; = p.L329Q on NM_001725.3) | Missense Mutation (SNP) | VAF 43/267 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- BRD8 | c.982G>T p.E328* (on ENST00000254900 / NM_139199.2; = p.E401* on NM_006696.4) | Nonsense Mutation (SNP) | VAF 10/82 reads (12%) | called by mutect2, varscan2
- BRDT | c.129A>T p.L43F | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- C10orf90 | c.1736G>T p.R579L | Missense Mutation (SNP) | VAF 79/567 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- C1orf116 | c.1224_1225insCCTG p.A409Pfs*31 | Frame Shift Ins (INS) | VAF 81/541 reads (15%) | called by mutect2, pindel, varscan2
- C20orf96 | c.879G>T p.Q293H (on ENST00000360321 / NM_153269.3; = p.Q292H on NM_080571.1) | Missense Mutation (SNP) | VAF 30/288 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.067); called by muse, mutect2
- CABS1 | c.348G>T p.M116I | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAPN5 | c.1577G>T p.R526L (on ENST00000456580; = p.R486L on NM_004055.5) | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CBX2 | c.1195G>T p.A399S | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0.01); called by muse, mutect2
- CCDC178 | c.614G>T p.W205L | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CCDC88B | c.2208G>T p.Q736H | Missense Mutation (SNP) | VAF 51/313 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- CCDC9B | c.1450_1456del p.L484Sfs*36 | Frame Shift Del (DEL) | VAF 24/113 reads (21%) | called by mutect2, pindel, varscan2
- CCL11 | c.77C>G p.A26G | Missense Mutation (SNP) | VAF 62/267 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CD1C | c.397C>G p.Q133E | Missense Mutation (SNP) | VAF 71/511 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CD1D | c.695dup p.P233Afs*10 | Frame Shift Ins (INS) | VAF 33/290 reads (11%) | called by pindel, varscan2
- CD209 | c.580C>A p.Q194K | Missense Mutation (SNP) | VAF 60/516 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.449); called by muse, varscan2
- CD22 | c.1431G>T p.W477C | Missense Mutation (SNP) | VAF 98/609 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CD53 | c.583A>T p.I195F | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- CD96 | c.776G>T p.S259I (on ENST00000283285 / NM_198196.3; = p.S243I on NM_005816.5) | Missense Mutation (SNP) | VAF 52/242 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- CDC5L | c.1837A>G p.I613V | Missense Mutation (SNP) | VAF 127/328 reads (39%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH22 | c.2302G>C p.D768H | Missense Mutation (SNP) | VAF 81/524 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH23 | c.550C>A p.R184S | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.575); called by muse, mutect2
- CDK11A | c.504G>C p.K168N (on ENST00000378633 / NM_001313896.2; = p.K178N on NM_024011.4) | Missense Mutation (SNP) | VAF 77/955 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.189); called by muse, mutect2
- CDKL3 | c.1512G>A p.M504I | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- CENPF | c.3679A>T p.S1227C | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- CENPF | c.3890T>A p.M1297K | Missense Mutation (SNP) | VAF 58/262 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CERKL | c.1179del p.L393Ffs*28 (on ENST00000339098 / NM_001030311.2; = p.L367Ffs*28 on NM_201548.5) | Frame Shift Del (DEL) | VAF 47/268 reads (18%) | called by mutect2, pindel, varscan2
- CFAP157 | c.1305C>A p.S435R | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- CFAP46 | c.4855C>G p.R1619G | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CFAP46 | c.1986+1G>T p.X662_splice | Splice Site (SNP) | VAF 23/83 reads (28%) | called by muse, mutect2, varscan2
- CFAP47 | c.8677C>T p.P2893S | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CFAP61 | c.1970C>A p.T657K | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- CHD7 | c.2246G>C p.R749P | Missense Mutation (SNP) | VAF 64/313 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CHRNA1 | c.189+2T>A p.X63_splice | Splice Site (SNP) | VAF 156/1025 reads (15%) | called by muse, mutect2, varscan2
- CHRNB2 | c.111_114dup p.P39Gfs*17 | Frame Shift Ins (INS) | VAF 99/742 reads (13%) | called by mutect2, pindel, varscan2
- CLCN1 | c.2752G>C p.G918R | Missense Mutation (SNP) | VAF 51/319 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- CLDND1 | c.641G>T p.W214L | Missense Mutation (SNP) | VAF 164/859 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNTNAP4 | c.2491T>A p.L831I | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); called by muse, varscan2
- CNTNAP5 | c.2179A>T p.S727C | Missense Mutation (SNP) | VAF 86/487 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- COL1A2 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 162/972 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- COL27A1 | c.2176C>A p.P726T | Missense Mutation (SNP) | VAF 70/294 reads (24%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- COL5A2 | c.2051G>T p.G684V | Missense Mutation (SNP) | VAF 143/669 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- COPG1 | c.2173A>T p.S725C | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- COQ2 | c.157G>T p.G53C | Missense Mutation (SNP) | VAF 50/299 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- CORIN | c.1673G>A p.S558N | Missense Mutation (SNP) | VAF 14/388 reads (4%) | SIFT tolerated (0.67); PolyPhen benign (0.02); called by muse, mutect2
- COX7B2 | c.227A>G p.K76R | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CPA6 | c.117-1G>T p.X39_splice | Splice Site (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
- CPAMD8 | c.1726+1G>A p.X576_splice (on ENST00000651564; = p.X529_splice on NM_015692.5) | Splice Site (SNP) | VAF 48/166 reads (29%) | called by muse, mutect2, varscan2
- CPNE6 | c.113C>A p.T38N | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- CRYL1 | c.740-2A>T p.X247_splice | Splice Site (SNP) | VAF 34/188 reads (18%) | called by muse, mutect2, varscan2
- CSF2RA | c.143G>T p.S48I | Missense Mutation (SNP) | VAF 54/588 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); called by muse, mutect2
- CSMD1 | c.834C>A p.N278K | Missense Mutation (SNP) | VAF 34/271 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- CSMD3 | c.3715+1G>T p.X1239_splice (on ENST00000297405 / NM_001363185.1; = p.X1135_splice on NM_052900.3) | Splice Site (SNP) | VAF 102/715 reads (14%) | called by muse, mutect2, varscan2
- CTSB | c.400T>A p.S134T | Missense Mutation (SNP) | VAF 62/304 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CUX2 | c.1748T>A p.L583Q | Missense Mutation (SNP) | VAF 25/301 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYP27A1 | c.331G>C p.A111P | Missense Mutation (SNP) | VAF 47/304 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- DBNL | c.836-8_840del p.X279_splice (on ENST00000448521 / NM_001014436.3; = p.X280_splice on NM_014063.7) | Splice Site (DEL) | VAF 33/190 reads (17%) | called by mutect2, pindel, varscan2
- DCC | c.27G>T p.W9C | Missense Mutation (SNP) | VAF 184/880 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.431); called by mutect2, varscan2
- DDO | c.86G>T p.C29F | Missense Mutation (SNP) | VAF 77/370 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- DGKK | c.668T>C p.M223T | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- DNAH8 | c.10384G>T p.A3462S | Missense Mutation (SNP) | VAF 18/407 reads (4%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.913); called by muse, mutect2
- DOCK3 | c.1792C>G p.L598V | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- DPYSL5 | c.261+1del | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- DRAP1 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.185); called by muse, mutect2
- DSCAM | c.2093del p.D698Afs*42 | Frame Shift Del (DEL) | VAF 76/452 reads (17%) | called by pindel, varscan2
- DST | c.19970G>T p.R6657M (on ENST00000361203 / NM_001374722.1; = p.R4354M on NM_015548.5) | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DTX1 | c.583A>C p.S195R | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- DUSP2 | c.310G>T p.D104Y | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DUSP8 | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYSF | c.6011dup p.R2006Pfs*3 | Frame Shift Ins (INS) | VAF 74/536 reads (14%) | called by mutect2, pindel, varscan2
- EARS2 | c.1122del p.K375Sfs*31 | Frame Shift Del (DEL) | VAF 46/290 reads (16%) | called by mutect2, pindel, varscan2
- EDIL3 | c.244C>A p.P82T | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EIF3E | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 54/293 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- ELF3 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2
- ELFN1 | c.44C>A p.A15D | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2
- ELFN1 | c.1689del p.D563Efs*121 | Frame Shift Del (DEL) | VAF 29/187 reads (16%) | called by mutect2, pindel, varscan2
- ELP1 | c.3746A>T p.D1249V | Missense Mutation (SNP) | VAF 90/391 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- EML2 | c.1510-4G>C | Splice Region (SNP) | VAF 94/335 reads (28%) | called by muse, mutect2, varscan2
- EPB41L3 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EPHA6 | c.1973T>A p.I658N (on ENST00000389672 / NM_001080448.3; = p.I50N on NM_173655.4) | Missense Mutation (SNP) | VAF 69/407 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ERAP1 | c.1219G>C p.A407P | Missense Mutation (SNP) | VAF 48/614 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ERMARD | c.7G>T p.V3L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2
- ERO1B | c.755del p.G252Dfs*57 | Frame Shift Del (DEL) | VAF 25/125 reads (20%) | called by mutect2, pindel, varscan2
- ESPNL | c.979G>T p.A327S | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.012); called by muse, mutect2
- ESYT2 | c.1650A>G p.S550= (on ENST00000613624; = p.S474= on NM_020728.3) | Splice Region (SNP) | VAF 68/347 reads (20%) | called by muse, mutect2, varscan2
- ESYT2 | c.297G>T p.E99D (on ENST00000613624; = p.E23D on NM_020728.3) | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.234); called by muse, mutect2
- EVX2 | c.38A>T p.E13V | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- EXT1 | c.820G>T p.G274W | Missense Mutation (SNP) | VAF 55/414 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM149A | c.1014G>T p.Q338H (on ENST00000356371 / NM_001367768.2; = p.Q47H on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/353 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FAM151B | c.165G>A p.M55I | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- FAM47B | c.1141C>T p.H381Y | Missense Mutation (SNP) | VAF 75/298 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FBN3 | c.1051C>A p.P351T | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- FBXL17 | c.2075G>T p.W692L | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- FBXO40 | c.294G>T p.E98D | Missense Mutation (SNP) | VAF 55/301 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FBXW10 | c.1529C>G p.S510C | Missense Mutation (SNP) | VAF 34/560 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- FER1L6 | c.5290G>T p.G1764C | Missense Mutation (SNP) | VAF 72/301 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FERMT2 | c.1735G>T p.G579W | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FJX1 | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 33/307 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLG | c.1865G>T p.S622I | Missense Mutation (SNP) | VAF 77/1109 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FLNC | c.2442G>C p.E814D | Missense Mutation (SNP) | VAF 98/520 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- FLT1 | c.111A>T p.K37N | Missense Mutation (SNP) | VAF 122/579 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FLYWCH1 | c.665G>T p.W222L (on ENST00000253928 / NM_001308068.2; = p.W221L on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FOXN1 | c.1021C>A p.R341S | Missense Mutation (SNP) | VAF 36/338 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FRY | c.5988C>G p.D1996E | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- FXYD5 | c.228G>C p.Q76H | Missense Mutation (SNP) | VAF 109/735 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- GABRR2 | c.878G>T p.R293I | Missense Mutation (SNP) | VAF 59/201 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GAPDHS | c.759C>A p.Y253* | Nonsense Mutation (SNP) | VAF 36/325 reads (11%) | called by muse, mutect2, varscan2
- GAPVD1 | c.2507-1G>A p.X836_splice (on ENST00000394104; = p.X863_splice on NM_015635.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 25/148 reads (17%) | called by muse, mutect2, varscan2
- GAS6 | c.468T>A p.D156E | Missense Mutation (SNP) | VAF 61/199 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- GATA3 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- GLIPR1 | c.458T>C p.V153A | Missense Mutation (SNP) | VAF 19/356 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- GLRA4 | c.249C>A p.S83R | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- GNS | c.49del p.R17Afs*48 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | called by mutect2, pindel, varscan2
- GOLM2 | c.1178A>T p.K393M | Missense Mutation (SNP) | VAF 156/907 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR107 | c.1351G>T p.G451* | Nonsense Mutation (SNP) | VAF 38/259 reads (15%) | called by muse, mutect2, varscan2
- GPR158 | c.2356G>A p.A786T | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.071); called by muse, mutect2
- GPRC5B | c.200C>A p.A67D | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- GSR | c.695G>C p.G232A | Missense Mutation (SNP) | VAF 86/930 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2
- GZF1 | c.1390G>A p.V464I | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- HDAC9 | c.1807C>T p.H603Y | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- HDGFL1 | c.434T>A p.L145Q | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); called by muse, mutect2
- HEATR3 | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HECW1 | c.2146C>A p.H716N | Missense Mutation (SNP) | VAF 59/332 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HES7 | c.224dup p.V77Gfs*94 | Frame Shift Ins (INS) | VAF 10/84 reads (12%) | called by mutect2, pindel, varscan2
- HIF3A | c.736A>T p.S246C (on ENST00000377670 / NM_152795.4; = p.S177C on NM_022462.4) | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- HMGCLL1 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- HOXA11 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, varscan2
- HOXD9 | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 118/421 reads (28%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- HP1BP3 | c.1549A>C p.K517Q | Missense Mutation (SNP) | VAF 98/688 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- HS3ST4 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- HSPG2 | c.1522G>T p.G508C | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HTR1E | c.202G>C p.D68H | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGF2 | c.283G>A p.D95N (on ENST00000434045 / NM_001127598.3; = p.D39N on NM_000612.6) | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGFBPL1 | c.749G>T p.G250V | Missense Mutation (SNP) | VAF 44/396 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV1D-42 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 64/395 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- IGKV3D-11 | c.219C>A p.N73K | Missense Mutation (SNP) | VAF 137/909 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IL5RA | c.1092-2A>T p.X364_splice | Splice Site (SNP) | VAF 22/109 reads (20%) | called by muse, mutect2, varscan2
- INVS | c.1319A>T p.Q440L | Missense Mutation (SNP) | VAF 96/435 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- IPO7 | c.1079A>G p.Y360C | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.202); called by muse, mutect2
- IQCE | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 34/269 reads (13%) | called by muse, mutect2, varscan2
- ISY1-RAB43 | c.851G>T p.G284V | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ITPR3 | c.5555A>T p.H1852L | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- IVD | c.744G>A p.M248I (on ENST00000651168; = p.M245I on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 141/825 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IWS1 | c.1410-2A>G p.X470_splice | Splice Site (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- JCAD | c.3908T>G p.V1303G | Missense Mutation (SNP) | VAF 61/224 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KCNA2 | c.626C>T p.T209I | Missense Mutation (SNP) | VAF 62/229 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- KCNC1 | c.40G>A p.V14M | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- KCNH1 | c.2206C>A p.P736T (on ENST00000271751 / NM_172362.3; = p.P709T on NM_002238.4) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- KCNH6 | c.1773C>A p.H591Q | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNQ2 | c.1973A>T p.Y658F (on ENST00000359125 / NM_172107.4; = p.Y630F on NM_004518.6) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- KHDC4 | c.373A>G p.T125A | Missense Mutation (SNP) | VAF 36/242 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); called by mutect2, varscan2
- KIAA0100 | c.6486G>T p.M2162I | Missense Mutation (SNP) | VAF 31/273 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KIAA0586 | c.3132G>T p.Q1044H (on ENST00000619416 / NM_001244190.2; = p.Q983H on NM_014749.5) | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); called by muse, mutect2
- KIR3DL3 | c.664G>T p.G222W | Missense Mutation (SNP) | VAF 75/224 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- KLHDC7A | c.1519G>T p.G507C | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- KLHL28 | c.1479G>C p.L493F | Missense Mutation (SNP) | VAF 46/484 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KRT6C | c.1523G>C p.G508A | Missense Mutation (SNP) | VAF 104/809 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KRTAP25-1 | c.257C>G p.A86G | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); called by muse, mutect2
- KRTAP4-3 | c.455C>A p.P152Q | Missense Mutation (SNP) | VAF 58/396 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- KTN1 | c.799G>T p.G267W | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LACTB2 | c.20G>C p.R7P | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LAMA2 | c.3274G>C p.E1092Q | Missense Mutation (SNP) | VAF 212/693 reads (31%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- LAMC1 | c.575G>C p.G192A | Missense Mutation (SNP) | VAF 57/354 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- LEKR1 | c.85G>C p.V29L | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); called by muse, mutect2
- LILRA1 | c.875G>T p.G292V | Missense Mutation (SNP) | VAF 111/518 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LINGO3 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LPA | c.4011G>T p.M1337I | Missense Mutation (SNP) | VAF 122/720 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.071); called by muse, varscan2
- LPA | c.4010T>A p.M1337K | Missense Mutation (SNP) | VAF 117/714 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.038); called by muse, varscan2
- LRBA | c.4945A>G p.N1649D | Missense Mutation (SNP) | VAF 95/475 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- LRRC73 | c.916C>A p.L306I | Missense Mutation (SNP) | VAF 95/553 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- LRRK2 | c.3838G>T p.E1280* | Nonsense Mutation (SNP) | VAF 46/320 reads (14%) | called by muse, mutect2, varscan2
- LTBP3 | c.914del p.G305Vfs*83 | Frame Shift Del (DEL) | VAF 31/214 reads (14%) | called by mutect2, pindel, varscan2
- LYST | c.8362G>T p.G2788* | Nonsense Mutation (SNP) | VAF 18/116 reads (16%) | called by muse, varscan2
- MACC1 | c.1816A>T p.I606F | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2
- MAPK3 | c.698G>T p.C233F | Missense Mutation (SNP) | VAF 32/312 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAS1L | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 62/459 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MATN1 | c.843C>A p.D281E | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- MCTP1 | c.1345G>A p.V449I | Missense Mutation (SNP) | VAF 46/392 reads (12%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, varscan2
- MED13L | c.3904G>A p.A1302T | Missense Mutation (SNP) | VAF 47/515 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.056); called by muse, mutect2
- MESP1 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MGARP | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- MMEL1 | c.2001C>A p.N667K | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- MMP1 | c.973C>A p.P325T | Missense Mutation (SNP) | VAF 106/653 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MMP13 | c.749G>T p.S250I | Missense Mutation (SNP) | VAF 93/704 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- MOCS1 | c.613A>C p.K205Q | Missense Mutation (SNP) | VAF 119/880 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.243); called by muse, mutect2
- MRGBP | c.113G>T p.C38F | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- MS4A12 | c.568G>T p.G190C | Missense Mutation (SNP) | VAF 65/375 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- MTBP | c.1710A>C p.K570N | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- MTMR6 | c.1020G>T p.W340C | Missense Mutation (SNP) | VAF 53/322 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTREX | c.2087_2089del p.V696del | In Frame Del (DEL) | VAF 12/84 reads (14%) | called by pindel, varscan2
- MUC16 | c.25793C>A p.P8598Q | Missense Mutation (SNP) | VAF 46/280 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- MUC16 | c.23992C>A p.P7998T | Missense Mutation (SNP) | VAF 54/287 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- MYH13 | c.1492C>A p.L498M | Missense Mutation (SNP) | VAF 183/935 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MYH4 | c.136T>G p.S46A | Missense Mutation (SNP) | VAF 131/693 reads (19%) | SIFT tolerated (0.98); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYH6 | c.2973C>G p.I991M | Missense Mutation (SNP) | VAF 95/446 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- MYH7 | c.327C>A p.Y109* | Nonsense Mutation (SNP) | VAF 126/700 reads (18%) | called by muse, mutect2, varscan2
- MYO15B | c.6665del p.G2222Afs*67 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | called by mutect2, pindel, varscan2
- MYO1E | c.2403G>T p.Q801H | Missense Mutation (SNP) | VAF 159/903 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MYO7B | c.2266G>A p.E756K | Missense Mutation (SNP) | VAF 79/347 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYOM3 | c.3865G>T p.G1289C | Missense Mutation (SNP) | VAF 30/428 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYOM3 | c.3864G>T p.K1288N | Missense Mutation (SNP) | VAF 30/429 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MYPOP | c.580T>A p.C194S | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MYT1L | c.2626G>C p.D876H | Missense Mutation (SNP) | VAF 80/432 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- NBAS | c.3590G>C p.R1197T | Missense Mutation (SNP) | VAF 90/548 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCOA6 | c.997G>T p.G333C | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- NDN | c.556C>A p.P186T | Missense Mutation (SNP) | VAF 57/307 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NEGR1 | c.566A>T p.D189V | Missense Mutation (SNP) | VAF 52/309 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- NEK1 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEURL2 | c.375G>T p.E125D | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- NGFR | c.154G>T p.G52C | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NIPAL4 | c.939C>A p.N313K | Missense Mutation (SNP) | VAF 115/639 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- NKX6-3 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 35/197 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- NLGN1 | c.1324G>T p.D442Y | Missense Mutation (SNP) | VAF 35/276 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NOTCH2 | c.4190A>T p.Y1397F | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- NPAP1 | c.2108C>G p.T703S | Missense Mutation (SNP) | VAF 83/595 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- NPC1L1 | c.1867G>A p.D623N | Missense Mutation (SNP) | VAF 103/607 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NPC1L1 | c.1866A>T p.E622D | Missense Mutation (SNP) | VAF 99/607 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NPFFR2 | c.199A>T p.T67S | Missense Mutation (SNP) | VAF 58/348 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NPHP1 | c.2024C>G p.A675G (on ENST00000393272 / NM_207181.4; = p.A676G on NM_000272.5) | Missense Mutation (SNP) | VAF 130/880 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NRK | c.3049A>G p.R1017G | Missense Mutation (SNP) | VAF 62/261 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRXN3 | c.3107T>G p.L1036R (on ENST00000335750 / NM_001330195.2; = p.L663R on NM_004796.6) | Missense Mutation (SNP) | VAF 40/268 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- NSL1 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- NUP210 | c.1220C>T p.S407L | Missense Mutation (SNP) | VAF 66/348 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OBSCN | c.18040C>A p.P6014T | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- OGDHL | c.2823G>T p.W941C | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OPN5 | c.764T>C p.M255T | Missense Mutation (SNP) | VAF 104/286 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.647); called by muse, mutect2
- OR10K1 | c.764C>A p.A255D | Missense Mutation (SNP) | VAF 85/491 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- OR10V1 | c.741A>T p.L247F | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- OR10X1 | c.665G>C p.G222A | Missense Mutation (SNP) | VAF 81/627 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- OR10Z1 | c.95T>A p.L32H | Missense Mutation (SNP) | VAF 74/470 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, varscan2
- OR2L3 | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 51/404 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2
- OR2M3 | c.116T>A p.F39Y | Missense Mutation (SNP) | VAF 56/438 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- OR2T27 | c.245T>A p.L82Q | Missense Mutation (SNP) | VAF 37/387 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OR2V1 | c.760G>T p.G254W | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR4D6 | c.46del p.E16Nfs*21 | Frame Shift Del (DEL) | VAF 30/167 reads (18%) | called by mutect2, pindel
- OR51A7 | c.71A>G p.H24R | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.342); called by muse, mutect2
- OR52A5 | c.766C>A p.L256I | Missense Mutation (SNP) | VAF 25/252 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- OR52N1 | c.400T>C p.Y134H | Missense Mutation (SNP) | VAF 42/414 reads (10%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.986); called by muse, mutect2
- OR56A3 | c.553A>G p.N185D | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- OR5M11 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- OR6B3 | c.926G>C p.S309T | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.023); called by muse, mutect2
- OR6N1 | c.500C>A p.P167Q | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- OSBPL6 | c.2738A>C p.N913T | Missense Mutation (SNP) | VAF 77/583 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- OTOA | c.217C>A p.L73M | Missense Mutation (SNP) | VAF 49/535 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.073); called by muse, mutect2
- OTOG | c.6023C>A p.P2008H | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- OTOG | c.7421G>T p.G2474V | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- P3H4 | c.958A>T p.M320L | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PABPC1 | c.1901C>A p.P634Q | Missense Mutation (SNP) | VAF 173/857 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PAG1 | c.735C>G p.I245M | Missense Mutation (SNP) | VAF 95/876 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- PAGE1 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAPPA2 | c.1238C>A p.S413Y | Missense Mutation (SNP) | VAF 59/313 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- PAX4 | c.317A>T p.Q106L | Missense Mutation (SNP) | VAF 72/712 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- PAX9 | c.771+1G>T p.X257_splice | Splice Site (SNP) | VAF 42/252 reads (17%) | called by muse, varscan2
- PCDH11Y | c.1712C>A p.T571K (on ENST00000400457 / NM_032973.2; = p.T560K on NM_032971.3) | Missense Mutation (SNP) | VAF 61/276 reads (22%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PCDH7 | c.2177C>A p.A726D | Missense Mutation (SNP) | VAF 49/234 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PCDHB11 | c.1990G>T p.D664Y | Missense Mutation (SNP) | VAF 53/315 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- PCDHGA3 | c.2363G>C p.S788T | Missense Mutation (SNP) | VAF 57/648 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.009); called by muse, mutect2
- PCDHGA8 | c.1311A>T p.Q437H | Missense Mutation (SNP) | VAF 52/284 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCF11 | c.3191A>T p.E1064V | Missense Mutation (SNP) | VAF 152/965 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- PDE10A | c.1157G>A p.G386D | Missense Mutation (SNP) | VAF 114/510 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDE6C | c.1227G>T p.K409N | Missense Mutation (SNP) | VAF 38/408 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- PEG3 | c.1534del p.E512Rfs*67 | Frame Shift Del (DEL) | VAF 83/314 reads (26%) | called by mutect2, pindel, varscan2
- PHOX2B | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIAS3 | c.128A>T p.H43L | Missense Mutation (SNP) | VAF 88/595 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKLR | c.697C>A p.P233T | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2
- PLAT | c.111C>G p.Y37* | Nonsense Mutation (SNP) | VAF 52/313 reads (17%) | called by muse, mutect2, varscan2
- PLBD2 | c.1330G>T p.V444L | Missense Mutation (SNP) | VAF 29/288 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- PLCB4 | c.3440T>A p.L1147Q | Missense Mutation (SNP) | VAF 31/243 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PLCH1 | c.1285C>T p.L429F (on ENST00000340059 / NM_001130960.2; = p.L441F on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/316 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHA2 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 16/338 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- PLXNB2 | c.5025del p.I1676Sfs*15 | Frame Shift Del (DEL) | VAF 39/148 reads (26%) | called by pindel, varscan2
- POGK | c.97A>C p.M33L | Missense Mutation (SNP) | VAF 50/361 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- POU4F1 | c.1049T>A p.F350Y | Missense Mutation (SNP) | VAF 39/322 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPIB | c.165_168del p.D56* | Frame Shift Del (DEL) | VAF 137/800 reads (17%) | called by pindel, varscan2
- PRDM5 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 46/371 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PRKCG | c.202G>T p.V68F | Missense Mutation (SNP) | VAF 89/285 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- PRKY | c.550G>T p.G184C | Missense Mutation (SNP) | VAF 58/321 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PROS1 | c.211G>T p.V71F | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- PROX2 | c.398G>T p.R133I | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- PSKH1 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPN12 | c.118A>T p.T40S | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- PTPRQ | c.4762C>A p.H1588N (on ENST00000616559; = p.H1546N on NM_001145026.2) | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2
- PTPRQ | c.6274A>T p.N2092Y (on ENST00000616559; = p.N2059Y on NM_001145026.2) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRU | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PXDNL | c.637C>A p.P213T | Missense Mutation (SNP) | VAF 71/434 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- RAB40A | c.715C>A p.L239I | Missense Mutation (SNP) | VAF 85/407 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- RAB8B | c.608G>T p.R203L | Missense Mutation (SNP) | VAF 44/450 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.124); called by muse, mutect2
- RAD51AP2 | c.102G>C p.K34N | Missense Mutation (SNP) | VAF 77/481 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RALGAPA2 | c.328+1G>C p.X110_splice | Splice Site (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- RASGRF2 | c.2756T>C p.L919P | Missense Mutation (SNP) | VAF 32/326 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM10 | c.719del p.K240Sfs*26 | Frame Shift Del (DEL) | VAF 77/312 reads (25%) | called by mutect2, pindel, varscan2
- RBM42 | c.1199C>G p.A400G | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- RBM47 | c.379_380del p.A127Sfs*3 | Frame Shift Del (DEL) | VAF 15/79 reads (19%) | called by pindel, varscan2
- REG3G | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 72/477 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- RETREG2 | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- RFX8 | c.977G>C p.R326T (on ENST00000646446; = p.R255T on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RFXAP | c.415A>C p.K139Q | Missense Mutation (SNP) | VAF 71/339 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RGPD8 | c.3694G>T p.D1232Y | Missense Mutation (SNP) | VAF 106/1443 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2
- RIMS2 | c.2494G>C p.G832R (on ENST00000666250 / NM_001348490.2; = p.G640R on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- RP1L1 | c.3089G>T p.G1030V | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPGRIP1 | c.1403C>A p.P468H | Missense Mutation (SNP) | VAF 92/912 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.26); called by muse, mutect2
- RSF1 | c.1563G>T p.E521D | Missense Mutation (SNP) | VAF 32/261 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- RTN4 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 81/522 reads (16%) | called by muse, mutect2, varscan2
- SALL4 | c.1147A>T p.K383* | Nonsense Mutation (SNP) | VAF 80/457 reads (18%) | called by muse, mutect2, varscan2
- SCN5A | c.5197C>G p.P1733A (on ENST00000333535 / NM_198056.3; = p.P1732A on NM_000335.5) | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- SEC16B | c.901G>T p.G301W | Missense Mutation (SNP) | VAF 65/314 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SELL | c.425T>A p.V142E (on ENST00000650983; = p.V129E on NM_000655.5) | Missense Mutation (SNP) | VAF 106/620 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SERINC3 | c.414dup p.A139Cfs*50 | Frame Shift Ins (INS) | VAF 56/369 reads (15%) | called by mutect2, pindel, varscan2
- SERPINB5 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 91/389 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SHROOM4 | c.2119C>A p.P707T | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIRPB2 | c.399G>T p.L133F | Missense Mutation (SNP) | VAF 57/359 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- SIRPB2 | c.11C>A p.T4K | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIRPG | c.1093T>A p.S365T | Missense Mutation (SNP) | VAF 43/263 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SIRPG | c.835C>A p.Q279K | Missense Mutation (SNP) | VAF 89/509 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SLC10A5 | c.1249G>T p.V417F | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC17A9 | c.396A>T p.Q132H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC24A5 | c.859C>G p.Q287E | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC36A1 | c.1078C>A p.P360T | Missense Mutation (SNP) | VAF 31/429 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC4A10 | c.2366C>A p.P789Q (on ENST00000446997 / NM_001354461.2; = p.P759Q on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/328 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC5A1 | c.1554del p.T519Rfs*72 | Frame Shift Del (DEL) | VAF 170/875 reads (19%) | called by mutect2, pindel, varscan2
- SLC6A3 | c.1636C>G p.P546A | Missense Mutation (SNP) | VAF 35/293 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- SLC9A4 | c.2195G>T p.S732I | Missense Mutation (SNP) | VAF 34/381 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.12); called by muse, mutect2
- SMG9 | c.697C>T p.Q233* | Nonsense Mutation (SNP) | VAF 31/107 reads (29%) | called by muse, mutect2, varscan2
- SNAP25 | c.553-1G>T p.X185_splice | Splice Site (SNP) | VAF 62/388 reads (16%) | called by muse, mutect2, varscan2
- SNX16 | c.52A>T p.S18C | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- SOBP | c.1546C>A p.P516T | Missense Mutation (SNP) | VAF 86/341 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SOBP | c.1910G>A p.G637D | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SP4 | c.1958G>T p.G653V | Missense Mutation (SNP) | VAF 58/382 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- SP9 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 90/393 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPDYE5 | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 75/741 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- SPOCD1 | c.2705G>T p.R902L | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SPTA1 | c.5297A>T p.E1766V | Missense Mutation (SNP) | VAF 140/884 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- ST8SIA5 | c.758_759del p.R253Qfs*61 | Frame Shift Del (DEL) | VAF 43/254 reads (17%) | called by pindel, varscan2
- STAC2 | c.1015G>T p.G339C | Missense Mutation (SNP) | VAF 53/208 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SULF1 | c.1921G>T p.D641Y | Missense Mutation (SNP) | VAF 54/467 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SVOPL | c.362T>C p.F121S | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- SWT1 | c.1058G>T p.R353L | Missense Mutation (SNP) | VAF 45/302 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYCP2L | c.1170G>T p.Q390H | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- SYTL2 | c.2692G>T p.D898Y (on ENST00000528231 / NM_001162951.2; = p.D874Y on NM_032943.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TCEAL1 | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- TDRD10 | c.71A>G p.Q24R | Missense Mutation (SNP) | VAF 52/402 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- TDRD12 | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TEX13A | c.1159G>T p.A387S | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- THEGL | c.786G>T p.L262F | Missense Mutation (SNP) | VAF 41/388 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, varscan2
- TIAM1 | c.2949del p.P984Qfs*29 | Frame Shift Del (DEL) | VAF 87/523 reads (17%) | called by mutect2, pindel, varscan2
- TKTL1 | c.1252A>T p.T418S | Missense Mutation (SNP) | VAF 51/242 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TLN2 | c.5676T>A p.S1892R | Missense Mutation (SNP) | VAF 55/296 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- TMEM132D | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM150B | c.51_54del p.I17Mfs*11 | Frame Shift Del (DEL) | VAF 40/136 reads (29%) | called by mutect2, pindel, varscan2
- TMEM63A | c.140_141dup p.G48Lfs*10 | Frame Shift Ins (INS) | VAF 51/258 reads (20%) | called by mutect2, pindel, varscan2
- TNRC18 | c.1895G>T p.R632L | Missense Mutation (SNP) | VAF 67/272 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- TNS3 | c.3025G>C p.D1009H | Missense Mutation (SNP) | VAF 90/540 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- TNS3 | c.1772_1773del p.R591Pfs*11 | Frame Shift Del (DEL) | VAF 41/226 reads (18%) | called by pindel, varscan2
- TOM1 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 56/305 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TPTE | c.839G>T p.R280L (on ENST00000618007 / NM_199261.4; = p.R262L on NM_199259.4) | Missense Mutation (SNP) | VAF 38/406 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.055); called by muse, mutect2
- TRIM10 | c.959A>T p.H320L | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- TRIM27 | c.185A>T p.Q62L | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- TRMT12 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 64/453 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- TRPM5 | c.2297G>T p.G766V | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRPM6 | c.890C>A p.P297H | Missense Mutation (SNP) | VAF 125/642 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TSHZ3 | c.2287G>T p.V763L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- TSPYL6 | c.363C>A p.H121Q | Missense Mutation (SNP) | VAF 50/278 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTLL6 | c.2596A>T p.M866L (on ENST00000393382 / NM_001130918.3; = p.M559L on NM_173623.3) | Missense Mutation (SNP) | VAF 22/374 reads (6%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2
- TTYH3 | c.1136del p.G379Afs*97 | Frame Shift Del (DEL) | VAF 45/166 reads (27%) | called by mutect2, pindel, varscan2
- UGT2A1 | c.478G>T p.A160S | Missense Mutation (SNP) | VAF 52/247 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UMPS | c.904del p.A302Qfs*7 | Frame Shift Del (DEL) | VAF 30/158 reads (19%) | called by mutect2, pindel, varscan2
- UNC13C | c.4357G>C p.A1453P | Missense Mutation (SNP) | VAF 76/561 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UNC93B1 | c.1334del p.G445Afs*4 | Frame Shift Del (DEL) | VAF 12/86 reads (14%) | called by mutect2, pindel
- USF1 | c.244A>T p.S82C | Missense Mutation (SNP) | VAF 69/363 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- USH2A | c.8440G>C p.V2814L | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- USP38 | c.426G>T p.Q142H | Missense Mutation (SNP) | VAF 118/627 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- USP47 | c.2260C>T p.H754Y (on ENST00000399455 / NM_001372095.1; = p.H666Y on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- VCX | c.37A>T p.K13* | Nonsense Mutation (SNP) | VAF 52/432 reads (12%) | called by muse, varscan2
- VGLL3 | c.496G>T p.V166F | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- WDR87 | c.4856C>A p.A1619E | Missense Mutation (SNP) | VAF 73/377 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- XYLT1 | c.1514A>T p.Y505F | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZBTB22 | c.1169G>T p.G390V | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ZBTB41 | c.1657G>T p.G553* | Nonsense Mutation (SNP) | VAF 24/128 reads (19%) | called by muse, mutect2, varscan2
- ZDBF2 | c.4600G>C p.D1534H | Missense Mutation (SNP) | VAF 47/222 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZFHX4 | c.4306A>G p.T1436A | Missense Mutation (SNP) | VAF 34/290 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- ZIC3 | c.197T>A p.L66Q | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZIK1 | c.514G>T p.V172F | Missense Mutation (SNP) | VAF 130/442 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- ZMYND8 | c.2212C>T p.P738S (on ENST00000311275 / NM_001363741.2; = p.P758S on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.055); called by muse, mutect2
- ZNF154 | c.1189A>T p.N397Y | Missense Mutation (SNP) | VAF 34/596 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.359); called by muse, mutect2
- ZNF229 | c.2197G>C p.V733L | Missense Mutation (SNP) | VAF 133/564 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF233 | c.1324C>T p.H442Y | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ZNF236 | c.50-1G>A p.X17_splice | Splice Site (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
- ZNF254 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF285 | c.298C>A p.P100T | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ZNF33A | c.116A>T p.D39V | Missense Mutation (SNP) | VAF 32/373 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ZNF469 | c.138G>T p.K46N | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- ZNF527 | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 33/194 reads (17%) | called by muse, mutect2, varscan2
- ZNF527 | c.1709G>C p.R570T | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ZNF560 | c.325C>A p.L109M | Missense Mutation (SNP) | VAF 76/452 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.074); called by muse, varscan2
- ZNF571 | c.1624G>T p.G542C | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ZNF609 | c.3826G>T p.G1276C | Missense Mutation (SNP) | VAF 69/408 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- ZNF793 | c.1087G>A p.G363R | Missense Mutation (SNP) | VAF 79/537 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- ZNF808 | c.1411G>T p.A471S | Missense Mutation (SNP) | VAF 84/362 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZNF808 | c.1872A>T p.R624S | Missense Mutation (SNP) | VAF 92/341 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, varscan2
- ZNF843 | c.337G>C p.A113P | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ZNF90 | c.3+1G>T p.X1_splice | Splice Site (SNP) | VAF 62/264 reads (23%) | called by muse, mutect2, varscan2
- ZSWIM2 | c.833G>T p.R278I | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, varscan2
- A4GALT | c.330G>A p.V110= | Silent (SNP) | VAF 53/257 reads (21%) | called by muse, mutect2, varscan2
- AC092143.1 | c.1362G>C p.T454= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as COSV59248654; called by muse, mutect2, varscan2
- ACKR1 | c.558G>T p.L186= | Silent (SNP) | VAF 45/232 reads (19%) | called by muse, mutect2, varscan2
- ADAMTS2 | c.660T>A p.P220= | Silent (SNP) | VAF 23/119 reads (19%) | called by muse, mutect2, varscan2
- ADARB2 | c.268C>A p.R90= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as COSV101187133; called by muse, mutect2
- ADCY8 | c.1068T>C p.C356= | Silent (SNP) | VAF 64/404 reads (16%) | called by muse, mutect2, varscan2
- AHNAK | c.14988G>T p.L4996= | Silent (SNP) | VAF 19/123 reads (15%) | called by muse, mutect2, varscan2
- AKAP12 | c.1383G>A p.K461= | Silent (SNP) | VAF 40/184 reads (22%) | called by muse, mutect2, varscan2
- ALDH3B2 | c.966G>T p.G322= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV62428427; called by muse, mutect2, varscan2
- AP3D1 | c.1077G>T p.R359= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100642389; called by muse, mutect2, varscan2
- APOBEC1 | c.213G>T p.T71= | Silent (SNP) | VAF 43/208 reads (21%) | catalogued as rs778791013, COSV57548665; called by muse, mutect2, varscan2
- ARHGAP25 | c.1536C>A p.S512= (on ENST00000409202 / NM_001007231.3; = p.S504= on NM_014882.3) | Silent (SNP) | VAF 42/226 reads (19%) | called by muse, mutect2, varscan2
- ASH1L | c.8343C>T p.Y2781= (on ENST00000368346 / NM_001366177.2; = p.Y2776= on NM_018489.3) | Silent (SNP) | VAF 38/260 reads (15%) | called by muse, mutect2, varscan2
- ATP10B | c.3339G>T p.V1113= | Silent (SNP) | VAF 63/355 reads (18%) | called by muse, mutect2, varscan2
- ATP6V1A | c.921G>A p.K307= | Silent (SNP) | VAF 22/431 reads (5%) | called by muse, mutect2
- BCL2L13 | c.93G>T p.L31= | Silent (SNP) | VAF 26/154 reads (17%) | called by muse, mutect2, varscan2
- BPIFB4 | c.1002C>A p.I334= | Silent (SNP) | VAF 45/346 reads (13%) | catalogued as rs754525384; called by muse, mutect2, varscan2
- BRINP3 | c.93G>A p.A31= | Silent (SNP) | VAF 86/632 reads (14%) | catalogued as rs762331502, COSV66538668; called by muse, mutect2, varscan2
- BRWD3 | c.2496A>C p.T832= | Silent (SNP) | VAF 47/184 reads (26%) | called by muse, mutect2, varscan2
- C12orf60 | c.9A>T p.S3= | Silent (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- C1orf94 | c.402G>T p.S134= | Silent (SNP) | VAF 42/175 reads (24%) | called by muse, mutect2, varscan2
- CALB2 | c.540G>T p.L180= | Silent (SNP) | VAF 62/262 reads (24%) | catalogued as COSV56939304; called by mutect2, varscan2
- CAPN11 | c.348A>C p.I116= | Silent (SNP) | VAF 48/279 reads (17%) | catalogued as rs771437989; called by muse, mutect2, varscan2
- CBLN2 | c.627G>C p.G209= | Silent (SNP) | VAF 89/530 reads (17%) | called by muse, mutect2, varscan2
- CCDC39 | c.2079C>T p.Y693= | Silent (SNP) | VAF 16/170 reads (9%) | catalogued as rs376782159; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CD53 | c.582G>A p.V194= | Silent (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- CDH18 | c.963C>T p.D321= | Silent (SNP) | VAF 9/170 reads (5%) | called by muse, mutect2
- CEL | c.1446A>T p.T482= (on ENST00000673714; = p.T479= on NM_001807.6) | Silent (SNP) | VAF 72/276 reads (26%) | catalogued as COSV60826304; called by muse, varscan2
- CNTNAP5 | c.2661C>A p.S887= | Silent (SNP) | VAF 98/606 reads (16%) | catalogued as COSV70492259; called by muse, mutect2, varscan2
- COL4A6 | c.3093G>T p.L1031= | Silent (SNP) | VAF 61/250 reads (24%) | called by muse, mutect2, varscan2
- COL6A6 | c.3636C>A p.T1212= | Silent (SNP) | VAF 28/379 reads (7%) | called by muse, mutect2
- CRB1 | c.516C>T p.C172= | Silent (SNP) | VAF 62/336 reads (18%) | called by muse, mutect2, varscan2
- CSMD3 | c.4851T>A p.T1617= (on ENST00000297405 / NM_001363185.1; = p.T1513= on NM_052900.3) | Silent (SNP) | VAF 114/721 reads (16%) | catalogued as COSV52270466; called by muse, mutect2, varscan2
- CUBN | c.10335A>T p.S3445= | Silent (SNP) | VAF 60/706 reads (8%) | called by muse, mutect2
- DAPL1 | c.393C>T p.V131= | Silent (SNP) | VAF 64/781 reads (8%) | called by muse, mutect2, varscan2
- DCN | c.999G>T p.P333= | Silent (SNP) | VAF 23/231 reads (10%) | called by muse, mutect2, varscan2
- DDX20 | c.234G>T p.R78= | Silent (SNP) | VAF 21/82 reads (26%) | called by muse, mutect2, varscan2
- DENND5B | c.2277G>A p.A759= | Silent (SNP) | VAF 54/571 reads (9%) | catalogued as rs758582816; called by muse, mutect2
- DNHD1 | c.4494C>T p.H1498= | Silent (SNP) | VAF 51/515 reads (10%) | catalogued as COSV54442349; called by muse, mutect2, varscan2
- DSG1 | c.1467C>T p.D489= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as rs200542064; called by muse, varscan2
- EIF4H | c.576A>T p.G192= | Silent (SNP) | VAF 11/112 reads (10%) | called by muse, mutect2
- ELFN1 | c.45C>A p.A15= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as COSV70036804; called by muse, mutect2
- ENAM | c.2223A>T p.I741= | Silent (SNP) | VAF 39/229 reads (17%) | called by muse, mutect2, varscan2
- ENTPD6 | c.1176G>T p.V392= | Silent (SNP) | VAF 28/160 reads (18%) | called by muse, mutect2
- EPHA2 | c.357C>T p.F119= | Silent (SNP) | VAF 124/693 reads (18%) | catalogued as COSV64455160; called by muse, mutect2, varscan2
- ESRRA | c.1131G>T p.R377= | Silent (SNP) | VAF 18/125 reads (14%) | called by mutect2, varscan2
- FAM124B | c.591G>T p.V197= | Silent (SNP) | VAF 45/246 reads (18%) | called by muse, mutect2, varscan2
- FAM3B | c.447C>T p.S149= | Silent (SNP) | VAF 78/528 reads (15%) | called by muse, mutect2, varscan2
- FAM98A | c.117C>T p.S39= | Silent (SNP) | VAF 36/238 reads (15%) | catalogued as rs1219425244; called by muse, mutect2, varscan2
- FASN | c.1803C>T p.L601= | Silent (SNP) | VAF 26/216 reads (12%) | catalogued as rs776075075, COSV60760399; ClinVar: likely benign; called by muse, mutect2, varscan2
- FBXL7 | c.1027C>A p.R343= | Silent (SNP) | VAF 66/285 reads (23%) | catalogued as rs375745885; called by muse, mutect2, varscan2
- FGF6 | c.321C>T p.S107= | Silent (SNP) | VAF 38/263 reads (14%) | catalogued as rs775761160, COSV57404079; called by muse, mutect2, varscan2
- FMR1NB | c.709A>C p.R237= | Silent (SNP) | VAF 36/183 reads (20%) | called by muse, mutect2, varscan2
- FNDC7 | c.1491G>A p.L497= | Silent (SNP) | VAF 111/576 reads (19%) | called by muse, mutect2, varscan2
- FOXD3 | c.1353A>T p.P451= | Silent (SNP) | VAF 126/536 reads (24%) | called by muse, mutect2, varscan2
- GGNBP2 | c.1668A>T p.T556= | Silent (SNP) | VAF 24/230 reads (10%) | called by muse, mutect2
- GJB3 | c.438C>A p.L146= | Silent (SNP) | VAF 76/759 reads (10%) | catalogued as COSV64904572; called by muse, mutect2, varscan2
- GP2 | c.828C>G p.T276= (on ENST00000381362 / NM_001007240.3; = p.T273= on NM_001502.4) | Silent (SNP) | VAF 34/478 reads (7%) | catalogued as COSV56892897; called by muse, mutect2
- GPS1 | c.105C>T p.Y35= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs910929184; called by muse, mutect2, varscan2
- GRM5 | c.3387C>A p.P1129= (on ENST00000305447 / NM_001143831.2; = p.P1097= on NM_000842.4) | Silent (SNP) | VAF 26/131 reads (20%) | called by muse, mutect2, varscan2
- GRM8 | c.1959C>A p.V653= | Silent (SNP) | VAF 51/445 reads (11%) | catalogued as COSV58852605, COSV58870765; called by muse, mutect2, varscan2
- HAPLN2 | c.21C>T p.L7= | Silent (SNP) | VAF 55/341 reads (16%) | called by muse, mutect2, varscan2
- HCN1 | c.2181G>T p.L727= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV57499791; called by mutect2, varscan2
- HDAC4 | c.2163C>T p.L721= | Silent (SNP) | VAF 37/364 reads (10%) | catalogued as rs765619324; called by muse, mutect2
- HTT | c.3999C>G p.S1333= | Silent (SNP) | VAF 111/566 reads (20%) | called by muse, mutect2, varscan2
- ICE1 | c.5421C>G p.V1807= | Silent (SNP) | VAF 39/483 reads (8%) | called by muse, mutect2
- IFNK | c.81C>T p.S27= | Silent (SNP) | VAF 53/298 reads (18%) | catalogued as rs779214416; called by muse, mutect2, varscan2
- IGLL5 | c.39T>C p.P13= | Silent (SNP) | VAF 76/360 reads (21%) | catalogued as rs1212789617, COSV73250988; called by muse, mutect2, varscan2
- IQSEC3 | c.951C>A p.R317= (on ENST00000538872 / NM_001170738.2; = p.R14= on NM_015232.1) | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV58284174; called by muse, mutect2, varscan2
- ITGAD | c.3018G>T p.L1006= | Silent (SNP) | VAF 25/213 reads (12%) | called by muse, mutect2, varscan2
- JAK1 | c.783G>T p.V261= | Silent (SNP) | VAF 35/286 reads (12%) | called by muse, mutect2, varscan2
- KBTBD3 | c.531A>G p.V177= | Silent (SNP) | VAF 35/204 reads (17%) | called by muse, mutect2, varscan2
- KCNH5 | c.2202C>G p.L734= | Silent (SNP) | VAF 11/170 reads (6%) | called by muse, mutect2
- KCNH7 | c.45G>T p.L15= | Silent (SNP) | VAF 49/328 reads (15%) | called by muse, mutect2, varscan2
- KDR | c.102C>A p.L34= | Silent (SNP) | VAF 44/321 reads (14%) | called by muse, mutect2, varscan2
- KIF26B | c.3027C>T p.P1009= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as rs528204544, COSV63654613; called by muse, mutect2, varscan2
- KIF26B | c.5532G>T p.A1844= | Silent (SNP) | VAF 30/119 reads (25%) | called by muse, mutect2, varscan2
- KIF2B | c.1557C>A p.T519= | Silent (SNP) | VAF 37/422 reads (9%) | called by muse, mutect2
- KLF6 | c.831G>C p.L277= | Silent (SNP) | VAF 162/950 reads (17%) | called by muse, mutect2, varscan2
- KRT23 | c.888C>A p.A296= | Silent (SNP) | VAF 93/462 reads (20%) | called by muse, mutect2, varscan2
- KRT74 | c.169C>A p.R57= | Silent (SNP) | VAF 159/973 reads (16%) | called by muse, mutect2, varscan2
- LAMA2 | c.4485G>T p.T1495= | Silent (SNP) | VAF 364/1096 reads (33%) | called by muse, mutect2, varscan2
- LAMA5 | c.3030G>T p.V1010= | Silent (SNP) | VAF 27/147 reads (18%) | called by muse, mutect2, varscan2
- LAMP5 | c.396T>A p.P132= | Silent (SNP) | VAF 42/301 reads (14%) | called by muse, mutect2, varscan2
- LATS1 | c.1845T>C p.I615= | Silent (SNP) | VAF 26/144 reads (18%) | called by muse, mutect2, varscan2
239 further variants in this file (0 protein-altering or splice-affecting, 113 silent, 126 other) are not listed here.
